Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81T, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81T-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology report as provided by the

Date report:

Material received:

Material: left adrenal

Macroscopic findings:

within the adrenal well circumscribed grey-reddish tumor (2.5x2.5x2cm). Complete resection.

Microscopic findings:

Alveolar growth pattern with cells of middle or large size with eosinophilic, partly granular and bright cytoplasm with eccentric nuclei with well recognizable nucleoli and partly with eosinophilic nuclear inclusion bodies. Some cells wit PAS positive inclusions some with brownish pigment. No atypical mitosis no highly atypical nuclei. No intravascular or periadrenal tumor cells. High degree of vasculature.

Immunopositivity for chromogranin A, synaptophysin, vimentin, protein100. Ki67 index <1%.

No nuclear staining for keratin, Lu5 and p53.

Conclusion:

Pheochromocytoma of the left adrenal

Translated by:

ICD-O-3
Pheochromocytoma NOS
8700/0
Site: (1) Adrenal gland NOS
C74.9
JW 10/17/13

Criteria	9/25/13	Yes	No
ICDAA Discrepancy			✓

Source: NCI Genomic Data Commons file 7619bd1b-4823-44f8-a2eb-3d58cfee1c79 (TCGA-WB-A81T.E0702A76-1D98-4959-8384-501F3FFCFE4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).